Gene-level copy-number profile of tumor specimen TCGA-04-1371-01A from TCGA case TCGA-04-1371, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.2 years (21,243 days).
Specimen TCGA-04-1371-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.7adacb86-5d5b-4894-a2d1-0eaa93a6fd5d.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1371-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 360 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3eaf4f4b-ad57-4a86-b9b7-c29431a8c898

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 2,407; copy number 2: 19,927; copy number 3: 20,856; copy number 4: 9,995; copy number 5: 2,914; copy number 6: 2,037; copy number 7: 565; copy number 8: 639; copy number 9: 20; copy number 10: 13; copy number 12: 262; copy number 13: 105; copy number 17: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1371-01A-01D-0452-01): tumor purity 0.89, ploidy 3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,434 genes in 43 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,711,277–31,587,686, 30 genes, copy number 5: MATN1, MATN1-AS1, AL137857.1, LAPTM5, MIR4420, AL137027.1, LINC01778, RN7SKP91, AL445235.1, SDC3, RN7SL371P, PUM1, AL356320.2, AL356320.1, SELENOWP1, AC114495.1, NKAIN1, SNRNP40, AC114495.2, ZCCHC17, AL451070.1, FABP3, SERINC2, AC209007.1, RNU6-40P, LDC1P, Y_RNA, LINC01226, AC114488.1, TINAGL1.
- chr1:45,010,950–45,618,904, 20 genes, copy number 5 (within-gene range 3–5): UROD, ZSWIM5, OSTCP5, LINC01144, HPDL, MUTYH, AL451136.1, TOE1, TESK2, PPIAP36, CCDC163, MMACHC, PRDX1, HMGB1P48, AKR1A1, AL355480.3, AL355480.1, NASP, AL355480.2, AL355480.4.
- chr1:112,523,514–113,685,923, 26 genes, copy number 6–12 (within-gene range 3–12): ST7L, CAPZA1, MRPL53P1, RNU7-70P, MOV10, AL603832.1, RHOC, AL603832.3, PPM1J, AL603832.2, TAFA3, NUTF2P4, LINC01356, LINC01357, AL390729.1, SLC16A1, AKR7A2P1, SLC16A1-AS1, AL390242.1, LRIG2-DT, LRIG2, RLIMP2, AL357055.1, AL357055.2, MAGI3, AL391058.1.
- chr2:75,455,994–85,310,387, 105 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:104,063,039–104,503,266, 2 genes, copy number 6: RAP1BP2, AC091804.1.
- chr3:118,004,819–119,146,068, 4 genes, copy number 5 (within-gene range 4–5): AC068633.1, AC068633.2, IGSF11, IGSF11-AS1.
- chr3:124,080,023–124,726,325, 5 genes, copy number 5 (within-gene range 4–5): KALRN, MIR5002, RPL7P15, MIR6083, RNU6-143P.
- chr3:125,225,669–128,825,942, 105 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:141,228,726–154,861,017, 228 genes, copy number 5–13 (within-gene range 4–13) (broad region; genes not listed).
- chr3:165,772,904–198,222,513, 629 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr6:165,327,287–165,988,078, 2 genes, copy number 5 (within-gene range 3–5): PDE10A, RNA5SP226.
- chr6:167,228,300–168,723,495, 32 genes, copy number 6: HPAT5, AL353747.3, AL353747.2, UNC93A, TTLL2, AL021331.1, TCP10L3, AL356123.1, LINC02538, AL356123.2, LINC02487, AL009178.1, LINC01558, AL009178.2, AL009178.3, AFDN-DT, AFDN, HGC6.3, KIF25-AS1, KIF25, FRMD1, AL611929.1, AL606970.5, AL606970.4, AL606970.2, AL606970.3, CTAGE13P, DACT2, AL606970.1, AL138918.1, SMOC2, AL136099.1.
- chr7:19,695,461–38,932,394, 385 genes, copy number 5–12 (broad region; genes not listed).
- chr7:40,964,667–51,389,114, 170 genes, copy number 5–6 (broad region; genes not listed).
- chr7:94,394,895–101,559,024, 227 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:68,848,737–75,034,558, 113 genes, copy number 6–8 (broad region; genes not listed).
- chr8:97,132,835–102,688,906, 133 genes, copy number 6–10 (broad region; genes not listed).
- chr10:36,432,882–42,367,974, 63 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr11:22,010,402–35,421,002, 179 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr11:62,116,470–62,331,813, 10 genes, copy number 9: AP002793.1, INCENP, EEF1DP8, SCGB1D1, SCGB2A1, AP003306.1, SCGB1D2, SCGB2A2, SCGB1D4, NPM1P35.
- chr12:19,089,151–19,720,801, 13 genes, copy number 6 (within-gene range 4–6): RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1.
- chr12:31,244,440–34,249,958, 82 genes, copy number 5 (broad region; genes not listed).
- chr12:50,256,238–68,234,686, 589 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr15:31,923,438–32,173,018, 1 gene, copy number 5 (within-gene range 1–5): CHRNA7.
- chr15:32,175,247–33,194,714, 36 genes, copy number 5 (within-gene range 3–5): Y_RNA, AC068448.1, AC139426.3, RNU6-18P, AC139426.1, AC139426.2, AC139426.4, DNM1P31, GOLGA8K, RN7SL185P, AC135983.1, ULK4P1, U8, DNM1P32, GOLGA8O, RN7SL539P, AC135983.5, AC135983.4, AC135983.3, AC135983.2, LINC02256, AC123768.3, AC123768.2, GOLGA8N, RN7SL286P, AC123768.1, ARHGAP11A, AC123768.4, SCG5, SCG5-AS1, AC090877.2, GREM1, FMN1, AC090877.1, AC018515.1, HNRNPA1P71.
- chr16:3,930,806–35,086,119, 1,006 genes, copy number 5 (broad region; genes not listed).
- chr18:20,946,906–24,544,154, 87 genes, copy number 6 (broad region; genes not listed).
- chr18:29,048,620–33,441,101, 66 genes, copy number 8 (broad region; genes not listed).
- chr19:4,675,224–5,340,803, 19 genes, copy number 8: DPP9, DPP9-AS1, AC005594.1, MIR7-3HG, MIR7-3, AC005523.1, FEM1A, AC005523.2, TICAM1, AC027319.1, PLIN3, ARRDC5, UHRF1, MIR4747, KDM4B, PTPRS, AC022517.1, RPL32P34, AC005790.1.
- chr19:9,810,267–15,697,174, 342 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr19:17,215,346–19,836,073, 152 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr19:22,128,627–23,512,656, 75 genes, copy number 7 (broad region; genes not listed).
- chr19:28,394,851–39,846,379, 438 genes, copy number 7–17 (broad region; genes not listed).
- chr20:6,065,966–6,780,246, 9 genes, copy number 8: AL118505.1, FERMT1, TARDBPP1, AL109618.1, AL109618.2, AL109618.3, CASC20, LINC01713, BMP2.
- chr20:10,385,779–11,926,609, 27 genes, copy number 6: SDAD1P2, MKKS, AL034430.1, AL034430.2, SLX4IP, AL035456.1, JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1, AL109837.2, AL109837.3, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1.
- chr20:15,892,355–17,735,871, 29 genes, copy number 6–8: AL079338.1, AL161941.1, PPIAP17, KIF16B, AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1, AL034428.1, SNRPB2, OTOR, AL121892.1, U3, RNU6-27P, AL359511.1, RNU1-131P, AL359511.2, AL359511.3, PCSK2, DYNLT3P1, BFSP1, RPS27AP2, AL132765.2, DSTN, RN7SKP69, AL132765.1, RRBP1, BANF2.
- chr20:20,854,121–21,115,197, 5 genes, copy number 5: MRPS11P1, AL133465.1, LINC00237, AL121759.2, RPL24P2.
- chr20:21,138,956–21,162,890, 2 genes, copy number 5: RNA5SP477, AL121759.1.
- chr20:30,294,550–64,313,132, 896 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr21:12,999,676–16,873,691, 89 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,403. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
